Somatic mutation profile of tumor specimen 0DPMS0 from CCDI case PBCBAI, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 7.4 years (2,685 days).
Specimen 0DPMS0: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3717a111-188c-4b82-a5f6-a0c8f125c4c2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DPMQO (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d208957c-c903-44d5-a7cf-2e1b988d0e36

The open-access MAF lists 4 somatic variants for this specimen: 4 protein-altering or splice-affecting.
By variant classification: Missense Mutation 4.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GLYCTK | c.1354G>A p.D452N | Missense Mutation (SNP) | VAF 20/216 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772211266, COSV59794709; called by muse, mutect2
- MUC16 | c.43199G>A p.R14400Q | Missense Mutation (SNP) | VAF 82/218 reads (38%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.129); catalogued as rs75155695, COSV66692222, COSV66697307; called by muse, mutect2, varscan2
- USP31 | c.1546C>T p.R516C | Missense Mutation (SNP) | VAF 81/193 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs765308963, COSV54849567; called by muse, mutect2, varscan2
- WDPCP | c.674C>T p.T225I | Missense Mutation (SNP) | VAF 65/212 reads (31%) | SIFT tolerated (0.44); PolyPhen benign (0.003); called by muse, mutect2, varscan2
